Surgical pathology report (de-identified scan), TCGA case TCGA-KS-A4I9, project TCGA-THCA (Thyroid Carcinoma), tissue source site University Of Michigan, specimen TCGA-KS-A4I9-01A (Primary Tumor).

[page 1 of 2]
PREVIOUS DIAGNOSIS INQUIRY

REPORT DATE:

BIRTHDATE

PAGE #: 1

SEX: F

ADM DATE:

PAT TYPE:

OPER DATE:

REQ DOC:

PROCEDURE: SPHS

VERIFIED BY:

A year-old female with papillary thyroid cancer.

PROCEDURE: SPGD

VERIFIED BY:

1. "Total thyroid." Received fresh in a small container is an 11.77 gm thyroid, right lobe 3.2 x 2.2 x 1.4 cm and left lobe 2.7 x 2.3 x 1.4 cm. The specimen is partially covered by a pink-tan capsule. A possible nodule is located in the lower isthmus. Specimen is inked as follows: Right lobe blue, left lobe black, isthmus yellow. The isthmus is remarkable for a 1.7 x 1.3 x 1.6 cm, tan-grey, well-circumscribed tumor that abuts the capsule. Focal areas of hemorrhage are noted within the tumor, however, no necrosis is noted. The remaining cut surface is a red-brown, granular thyroid parenchyma. No other lesions are noted.

1A-C. Isthmus tumor.

1D-F. Right lobe superior to inferior.

1G-I. Left lobe superior to inferior.

2. "Level VI lymph node, central neck." Received in formalin in a small container is a 3.5 x 2.2 x 1.3 cm aggregate of yellow, fibroadipose tissue. Several possible lymph nodes are identified ranging up to 0.3 cm.

2A. Eight possible lymph node. Fat retained.

PROCEDURE: SPMI

VERIFIED BY:

PAPILLARY THYROID CARCINOMA

Size of largest primary tumor: 1.7 cm

Location(s): Isthmus

Capsular Invasion: No

Vascular Invasion: No

Margins: Negative

Extrathyroidal extension: No

Lymph node metastases: No

Extranodal extension: N/A

SIDE

LEVEL

#POSITIVE NODES

#TOTAL NODES

ICD-0.3

Carcinoma, papillary, thyroid 8260/3
Site: thyroid, NOS C73.9

10/11/12

[page 2 of 2]
PREVIOUS DIAGNOSIS INQUIRY

REPORT DATE:

BIRTHDATE:

PAGE #:

2

SEX: F

ADM DATE:

PAT TYPE:

OPER DATE:

Central

VI

0

5

PROCEDURE: SPDX

VERIFIED BY:

1. Thyroid, total thyroidectomy: Papillary thyroid carcinoma (1.7 cm). Margins free. See template above.

2. Central neck, level VI lymph nodes, excision: Five lymph nodes negative for carcinoma. Benign thymic tissue identified.

I, [REDACTED], the signing staff pathologist, have personally examined and interpreted the slides from this case.

Code

Source: NCI Genomic Data Commons file 8776369b-23ff-48cd-b6e8-5652d0c5ba4e (TCGA-KS-A4I9.C4D74382-93BC-4798-83C5-DD669AD67794.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).